Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A221, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A221-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE: Postmenopausal.

PROCEDURE: Total abdominal hysterectomy, bilateral salpingo-oophorectomy.

SPECIFIC CLINICAL QUESTION: Not provided.

OUTSIDE TISSUE DIAGNOSIS: Not provided.

PRIOR MALIGNANCY: Not provided.

CHEMORADIATION THERAPY: Not provided.

OTHER DISEASES: Not provided.

1CD-0-3

Carcinoma, endometrioid, NOS 8380/3

Site: Endometrium c54.1

hw
3/28/11**FINAL DIAGNOSIS:**

Collection Date:

PART 1: UTERUS AND BOTH ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (86 GRAMS) -

- A. ENDOMETRIUM WITH HIGH-GRADE POORLY DIFFERENTIATED MIXED EPITHELIAL ADENOCARCINOMA: ENDOMETRIOID WITH SQUAMOUS DIFFERENTIATION, NUCLEAR GRADE 3; AND CLEAR CELL CARCINOMA COMPONENT (10%), WITH EXTENSIVE NECROSIS, INVOLVING ABOUT 85% OF ENDOMETRIAL SURFACE AND PENETRATING ABOUT 80% OF MYOMETRIAL THICKNESS (1F), WITH LYMPHOVASCULAR INVASION (1G) (see comment).**
- B. SUPERFICIAL ADENOMYOSIS.**
- C. LOWER UTERINE SEGMENT ENDOMETRIAL POLYP.**
- D. CHRONIC CYSTIC CERVICITIS.**
- E. MEDIAL CALCIFICATION OF MYOMETRIAL BLOOD VESSELS.**
- F. RIGHT AND LEFT OVARIES WITH EPITHELIAL INCLUSIONS, NO TUMOR SEEN.**
- G. LEFT FALLOPIAN TUBE, NO TUMOR SEEN.**
- H. RIGHT FALLOPIAN TUBE WITH PARATUBAL CYST, NO TUMOR SEEN.**

PART 2: OMENTUM, OMENTECTOMY -
OMENTUM, NO TUMOR SEEN.**PART 3: SOFT TISSUE, LEFT ABDOMINAL PERITONEUM, BIOPSY -**
MESOTHELIAL-LINED FIBROVASCULAR ADIPOSE TISSUE, NO TUMOR SEEN.**PART 4: SOFT TISSUE, RIGHT PELVIC PERITONEUM, BIOPSY -**
MESOTHELIAL-LINED FIBROVASCULAR ADIPOSE TISSUE, NO TUMOR SEEN.**PART 5: LYMPH NODES, LEFT PELVIC, DISSECTION -**
EIGHT LYMPH NODES, FREE OF TUMOR (0/8).**PART 6: LYMPH NODES, LEFT COMMON ILIAC, DISSECTION -**
ONE LYMPH NODE, FREE OF TUMOR (0/1).**PART 7: LYMPH NODES, LEFT PERIAORTIC, DISSECTION -**
ONE LYMPH NODE FREE OF TUMOR (0/1).**PART 8: LYMPH NODES, RIGHT PELVIC, DISSECTION -**
FIVE LYMPH NODES, FREE OF TUMOR (0/5).**PART 9: LYMPH NODES, RIGHT PERIAORTIC, DISSECTION -**
THREE LYMPH NODES, FREE OF TUMOR (0/3).**COMMENT:**

This endometrial adenocarcinoma represents a FIGO stage 1B, G3. The pelvic wash cytology (blinded) is negative for malignant cells.

The patient's previous endometrial curetting with endometrial carcinoma, grade 3 (blinded) is noted.

CASE SYNOPSIS:**SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA: HYSTERECTOMY SPECIMENS****TUMOR TYPE:** Mixed carcinoma, Endometrioid: 90%, Clear cell: 10%
HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Poorly differentiated (FIGO 3)

Poorly differentiated

Grade 3

ARCHITECTURAL GRADE:**NUCLEAR GRADE:****TUMOR SIZE:**

Maximum dimension: 45 mm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 90%, Posterior endomyometrium: 80%

Greater than or equal to 1/2 thickness of myometrium

Yes

DEPTH OF INVASION:**ANGIOLYMPHATIC INVASION:****OTHER:**

Endometrial polyp, Adenomyosis

LYMPH NODES POSITIVE:

Number of lymph nodes positive: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 18

T STAGE, PATHOLOGIC:

pT1b

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

Not applicable

FIGO STAGE:

1B

	Yes	No
ITPAA Discrepancy		
Case is (clin.):		

Source: NCI Genomic Data Commons file 20e689a0-ee54-4e97-9c06-9c8071e5999f (TCGA-BG-A221.58D68577-9022-4EF3-82E9-6EE159D41947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).